Somatic mutation profile of tumor specimen ALCH-AE8O-TTP1-A (aliquot ALCH-AE8O-TTP1-A-1-0-D-A605-36) from ALCHEMIST case ALCH-AE8O, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 55.8 years (20,398 days).
Specimen ALCH-AE8O-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6bf85d28-220a-42d4-9e0b-5c0feacc652c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-AE8O-NB1-A (Blood Derived Normal), aliquot ALCH-AE8O-NB1-A-1-0-D-A605-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d1e6a100-e8fa-4e61-8709-5d41453b07eb

The open-access MAF lists 282 somatic variants for this specimen: 190 protein-altering or splice-affecting, 57 silent, 35 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 150, Silent 57, Nonsense Mutation 18, Intron 15, Frame Shift Del 10, RNA 7, Splice Site 6, 3'UTR 5, Frame Shift Ins 3, 5'UTR 3, 5'Flank 3, 3'Flank 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 185/732 reads (25%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.314del p.G105Afs*18 | Frame Shift Del (DEL) | VAF 60/221 reads (27%) | catalogued as rs1567555907, COSV52708806, COSV52766179, COSV52793434; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- ABCC12 | c.2323G>T p.G775* | Nonsense Mutation (SNP) | VAF 76/368 reads (21%) | catalogued as COSV60918127; called by muse, mutect2, varscan2
- ADAR | c.701C>T p.S234F | Missense Mutation (SNP) | VAF 47/656 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs769223848; called by muse, mutect2
- AP3B1 | c.1961T>C p.I654T | Missense Mutation (SNP) | VAF 38/736 reads (5%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as rs780402652, COSV54875623; called by muse, mutect2
- APOB | c.10676T>C p.I3559T | Missense Mutation (SNP) | VAF 99/565 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.81); catalogued as rs1553382934; called by muse, mutect2, varscan2
- BMP1 | c.2047G>A p.V683M | Missense Mutation (SNP) | VAF 67/268 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.603); catalogued as rs781187309, COSV60480899; called by muse, mutect2, varscan2
- C4orf54 | c.2333G>T p.G778V | Missense Mutation (SNP) | VAF 45/126 reads (36%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.998); catalogued as rs972550149; called by muse, mutect2, varscan2
- CDIPT | c.604G>C p.A202P | Missense Mutation (SNP) | VAF 28/300 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV54889446; called by muse, mutect2
- CLDN8 | c.202G>T p.D68Y | Missense Mutation (SNP) | VAF 55/233 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54525871; called by muse, mutect2, varscan2
- CMTM4 | c.442G>A p.G148R | Missense Mutation (SNP) | VAF 47/250 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.109); catalogued as rs138530024, COSV100411952; called by muse, mutect2, varscan2
- COL7A1 | c.6007G>T p.G2003W | Missense Mutation (SNP) | VAF 71/529 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM960408; called by muse, mutect2, varscan2
- DOCK11 | c.268G>T p.E90* | Nonsense Mutation (SNP) | VAF 46/570 reads (8%) | catalogued as COSV52244584, COSV52246064; called by muse, mutect2
- DYSF | c.1274C>T p.A425V | Missense Mutation (SNP) | VAF 62/611 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs146588926; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- EPHA3 | c.58G>T p.G20W | Missense Mutation (SNP) | VAF 77/470 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.66); catalogued as COSV60731820; called by muse, mutect2, varscan2
- EVX2 | c.199G>A p.A67T | Missense Mutation (SNP) | VAF 78/886 reads (9%) | SIFT tolerated (0.31); PolyPhen benign (0.005); catalogued as COSV57962699; called by muse, mutect2
- F13B | c.1331G>T p.W444L | Missense Mutation (SNP) | VAF 196/702 reads (28%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV100803542; called by muse, mutect2, varscan2
- FAM170A | c.535A>G p.R179G | Missense Mutation (SNP) | VAF 53/286 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.691); catalogued as rs768999191, COSV100088848; called by muse, mutect2, varscan2
- FBLN1 | c.1058G>C p.R353P | Missense Mutation (SNP) | VAF 134/805 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as COSV53052481; called by muse, mutect2, varscan2
- FBN2 | c.4417C>G p.R1473G | Missense Mutation (SNP) | VAF 173/903 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.745); catalogued as COSV52522869; called by muse, mutect2, varscan2
- FMN2 | c.2849G>T p.G950V | Missense Mutation (SNP) | VAF 16/124 reads (13%) | SIFT tolerated, low confidence (0.26); PolyPhen possibly damaging (0.598); catalogued as COSV60459851; called by muse, varscan2
- FOSL2 | c.599C>T p.S200L | Missense Mutation (SNP) | VAF 79/316 reads (25%) | SIFT tolerated (0.46); PolyPhen benign (0.001); catalogued as rs773239010, COSV53104112; called by muse, mutect2, varscan2
- GABRG3 | c.522G>T p.Q174H | Missense Mutation (SNP) | VAF 54/274 reads (20%) | SIFT tolerated (0.67); PolyPhen benign (0.158); catalogued as COSV104414544; called by muse, mutect2, varscan2
- GRIK5 | c.652G>T p.A218S | Missense Mutation (SNP) | VAF 9/186 reads (5%) | SIFT tolerated (0.09); PolyPhen benign (0.329); catalogued as COSV99491129; called by muse, mutect2
- GUCY2F | c.1131C>G p.S377R | Missense Mutation (SNP) | VAF 121/429 reads (28%) | SIFT tolerated (0.3); PolyPhen benign (0.007); catalogued as COSV54306887; called by muse, mutect2, varscan2
- HNRNPCL1 | c.788G>T p.G263V | Missense Mutation (SNP) | VAF 188/570 reads (33%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as COSV58610662; called by muse, mutect2, varscan2
- HPSE2 | c.770G>T p.W257L | Missense Mutation (SNP) | VAF 152/513 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV65183582; called by mutect2, varscan2
- KCNA10 | c.182C>A p.T61K | Missense Mutation (SNP) | VAF 66/275 reads (24%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.415); catalogued as rs148829307; called by muse, mutect2, varscan2
- KLHL4 | c.823C>A p.L275I | Missense Mutation (SNP) | VAF 14/382 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV64138964; called by muse, mutect2
- LILRB4 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 36/137 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.676); catalogued as COSV54406647; called by muse, mutect2, varscan2
- LIPI | c.1067G>C p.C356S | Missense Mutation (SNP) | VAF 65/316 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.272); catalogued as COSV60714404; called by muse, mutect2, varscan2
- MINAR1 | c.2222G>T p.R741L | Missense Mutation (SNP) | VAF 80/274 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.072); catalogued as rs753895773, COSV59585126, COSV59585736; called by muse, mutect2, varscan2
- MSGN1 | c.146C>A p.P49Q | Missense Mutation (SNP) | VAF 57/285 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV99808761; called by muse, mutect2, varscan2
- MYH4 | c.361C>T p.L121F | Missense Mutation (SNP) | VAF 157/553 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.437); catalogued as COSV55112545; called by muse, mutect2, varscan2
- NDOR1 | c.1573G>A p.A525T | Missense Mutation (SNP) | VAF 103/295 reads (35%) | SIFT tolerated, low confidence (0.66); PolyPhen benign (0.003); catalogued as rs754438616; called by muse, mutect2, varscan2
- NEU2 | c.454C>T p.R152W | Missense Mutation (SNP) | VAF 20/224 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.723); catalogued as rs760542299, COSV52092700; called by muse, mutect2
- NOTCH4 | c.2225G>T p.G742V | Missense Mutation (SNP) | VAF 81/426 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV66681441; called by muse, mutect2, varscan2
- OR10T2 | c.479C>A p.A160D | Missense Mutation (SNP) | VAF 106/461 reads (23%) | SIFT tolerated (0.53); PolyPhen possibly damaging (0.763); catalogued as COSV57782157; called by muse, mutect2, varscan2
- OR2L3 | c.788C>A p.S263Y | Missense Mutation (SNP) | VAF 181/540 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.151); catalogued as COSV63456838; called by muse, mutect2, varscan2
- OR4A5 | c.646G>T p.G216* | Nonsense Mutation (SNP) | VAF 73/365 reads (20%) | catalogued as COSV100157337, COSV60521739; called by muse, mutect2, varscan2
- OR5M1 | c.793G>T p.E265* | Nonsense Mutation (SNP) | VAF 94/405 reads (23%) | catalogued as COSV73202058, COSV73202444; called by muse, mutect2, varscan2
- OR5T3 | c.844C>T p.H282Y | Missense Mutation (SNP) | VAF 21/277 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.048); catalogued as COSV100282988; called by muse, mutect2
- PARP4 | c.3064G>T p.G1022* | Nonsense Mutation (SNP) | VAF 64/325 reads (20%) | catalogued as rs748091610, COSV67963052; called by muse, mutect2, varscan2
- PCDHA5 | c.189C>A p.F63L | Missense Mutation (SNP) | VAF 185/1007 reads (18%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.288); catalogued as COSV65349933; called by muse, mutect2, varscan2
- POU1F1 | c.662T>C p.I221T | Missense Mutation (SNP) | VAF 8/228 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV60156960; called by muse, mutect2
- RET | c.1382C>A p.T461N | Missense Mutation (SNP) | VAF 212/795 reads (27%) | SIFT tolerated (0.21); PolyPhen benign (0.017); catalogued as COSV60706201; called by muse, mutect2, varscan2
- RFX6 | c.160G>A p.G54R | Missense Mutation (SNP) | VAF 79/244 reads (32%) | SIFT tolerated, low confidence (0.65); PolyPhen benign (0); catalogued as rs762141708; called by muse, mutect2, varscan2
- SH2D7 | c.710G>A p.G237D | Missense Mutation (SNP) | VAF 34/332 reads (10%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.497); catalogued as rs772060849; called by muse, mutect2, varscan2
- SHISA9 | c.1138C>T p.R380W | Missense Mutation (SNP) | VAF 43/566 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV69631753; called by muse, mutect2
- SLC1A6 | c.112C>T p.R38C | Missense Mutation (SNP) | VAF 120/447 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as rs1301909733, COSV99694151; called by muse, mutect2, varscan2
- SOWAHD | c.75C>A p.C25* | Nonsense Mutation (SNP) | VAF 20/172 reads (12%) | catalogued as COSV59649573; called by muse, mutect2, varscan2
- SPATA31A6 | c.2023C>A p.P675T | Missense Mutation (SNP) | VAF 84/815 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.055); catalogued as rs753766498, COSV100253849, COSV100253915; called by muse, mutect2, varscan2
- TNXB | c.9539A>T p.E3180V (on ENST00000647633; = p.E2933V on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 55/201 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.419); catalogued as COSV64483315; called by muse, mutect2, varscan2
- TRIM58 | c.1076G>T p.G359V | Missense Mutation (SNP) | VAF 91/409 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.472); catalogued as COSV63571192; called by muse, mutect2, varscan2
- TRIM64C | c.678G>T p.M226I | Missense Mutation (SNP) | VAF 161/762 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.32); catalogued as COSV73267232; called by muse, mutect2, varscan2
- TTN | c.57223G>C p.E19075Q (on ENST00000591111; = p.E11651Q on NM_003319.4) | Missense Mutation (SNP) | VAF 44/192 reads (23%) | PolyPhen benign (0.391); catalogued as rs548071435; called by muse, mutect2, varscan2
- UBN1 | c.1015C>T p.L339F | Missense Mutation (SNP) | VAF 138/681 reads (20%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.641); catalogued as rs755464006; called by muse, mutect2, varscan2
- USP26 | c.1375G>A p.E459K | Missense Mutation (SNP) | VAF 224/824 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63708271, COSV63708389, COSV63709428; called by muse, mutect2, varscan2
- VSIG4 | c.1182G>T p.E394D | Missense Mutation (SNP) | VAF 120/402 reads (30%) | SIFT tolerated (0.17); PolyPhen benign (0.055); catalogued as COSV101038354; called by muse, mutect2, varscan2
- XIRP2 | c.8549C>A p.S2850Y (on ENST00000628543; = p.S3025Y on NM_152381.6) | Missense Mutation (SNP) | VAF 80/299 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV99749698; called by muse, mutect2, varscan2
- ZSWIM5 | c.2467C>T p.R823* | Nonsense Mutation (SNP) | VAF 38/302 reads (13%) | catalogued as rs200748429, COSV62735634; called by muse, mutect2, varscan2
- ABCC12 | c.942G>A p.M314I | Missense Mutation (SNP) | VAF 44/194 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.919); called by muse, mutect2, varscan2
- ADAM22 | c.2576+5G>A | Splice Region (SNP) | VAF 14/246 reads (6%) | called by muse, mutect2
- ADAMTSL3 | c.3591G>T p.R1197S | Missense Mutation (SNP) | VAF 39/171 reads (23%) | SIFT tolerated (0.44); PolyPhen benign (0.438); called by muse, mutect2, varscan2
- AKR1A1 | c.217G>T p.E73* | Nonsense Mutation (SNP) | VAF 34/132 reads (26%) | called by muse, mutect2, varscan2
- AQP10 | c.287C>A p.P96H | Missense Mutation (SNP) | VAF 145/787 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- ARHGAP6 | c.614C>A p.S205* | Nonsense Mutation (SNP) | VAF 13/141 reads (9%) | called by muse, mutect2
- ATXN7L1 | c.2390G>T p.G797V | Missense Mutation (SNP) | VAF 42/186 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.96); called by muse, varscan2
- B4GALNT4 | c.786del p.W262Cfs*8 | Frame Shift Del (DEL) | VAF 83/410 reads (20%) | called by mutect2, pindel, varscan2
- C9orf131 | c.205T>C p.C69R | Missense Mutation (SNP) | VAF 68/439 reads (15%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.568); called by muse, mutect2, varscan2
- CARNMT1 | c.976G>T p.D326Y | Missense Mutation (SNP) | VAF 25/144 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- CASC3 | c.1325del p.P442Qfs*28 | Frame Shift Del (DEL) | VAF 79/559 reads (14%) | called by mutect2, pindel, varscan2
- CATSPER2 | c.1207G>A p.D403N (on ENST00000321596 / NM_001282309.3; = p.D405N on NM_172095.4) | Missense Mutation (SNP) | VAF 75/391 reads (19%) | SIFT tolerated (0.53); PolyPhen benign (0.087); called by muse, mutect2, varscan2
- CCDC171 | c.2339A>T p.E780V | Missense Mutation (SNP) | VAF 70/738 reads (9%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.529); called by muse, mutect2
- CD200R1 | c.364G>T p.V122L (on ENST00000471858 / NM_170780.3; = p.V145L on NM_138806.4) | Missense Mutation (SNP) | VAF 98/731 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CDH15 | c.580C>A p.L194M | Missense Mutation (SNP) | VAF 136/504 reads (27%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- CDH4 | c.247G>T p.G83W | Missense Mutation (SNP) | VAF 141/695 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- CFP | c.982A>G p.I328V | Missense Mutation (SNP) | VAF 24/364 reads (7%) | SIFT tolerated (0.39); PolyPhen benign (0); called by muse, mutect2
- CHCHD3 | c.194G>T p.R65I | Missense Mutation (SNP) | VAF 66/410 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.632); called by muse, mutect2, varscan2
- CNGB1 | c.2452C>T p.L818F | Missense Mutation (SNP) | VAF 155/866 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.059); called by muse, mutect2, varscan2
- CNTN1 | c.1050G>T p.W350C | Missense Mutation (SNP) | VAF 211/750 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.75); called by muse, mutect2, varscan2
- CNTNAP5 | c.1412C>A p.A471E | Missense Mutation (SNP) | VAF 101/456 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.66); called by muse, mutect2, varscan2
- COL9A1 | c.1361del p.G454Efs*23 | Frame Shift Del (DEL) | VAF 99/465 reads (21%) | called by mutect2, pindel, varscan2
- CROCC2 | c.2044G>T p.E682* | Nonsense Mutation (SNP) | VAF 5/21 reads (24%) | called by muse, mutect2, varscan2
- CSPG4 | c.245G>T p.R82L | Missense Mutation (SNP) | VAF 51/247 reads (21%) | SIFT tolerated (0.64); PolyPhen benign (0.313); called by muse, mutect2, varscan2
- CYLD | c.803A>T p.D268V | Missense Mutation (SNP) | VAF 56/218 reads (26%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DCAF4L2 | c.119C>A p.A40D | Missense Mutation (SNP) | VAF 138/838 reads (16%) | SIFT tolerated (0.29); PolyPhen benign (0); called by mutect2, varscan2
- DGCR2 | c.1000G>T p.D334Y | Missense Mutation (SNP) | VAF 79/401 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- DIS3 | c.2006T>C p.L669P | Missense Mutation (SNP) | VAF 105/328 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DMXL1 | c.8201G>T p.R2734I | Missense Mutation (SNP) | VAF 52/259 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- DNAH9 | c.5125C>T p.Q1709* | Nonsense Mutation (SNP) | VAF 23/311 reads (7%) | called by muse, mutect2
- DNAI1 | c.545A>T p.Q182L | Missense Mutation (SNP) | VAF 195/705 reads (28%) | SIFT tolerated (0.29); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- DNAJB4 | c.165G>C p.L55F | Missense Mutation (SNP) | VAF 120/542 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DOT1L | c.2301del p.A768Hfs*14 | Frame Shift Del (DEL) | VAF 69/347 reads (20%) | called by mutect2, pindel, varscan2
- EOGT | c.239G>T p.W80L | Missense Mutation (SNP) | VAF 81/505 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- EP400 | c.7179C>G p.I2393M | Missense Mutation (SNP) | VAF 74/282 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.509); called by muse, mutect2, varscan2
- EPHA3 | c.2555C>T p.A852V | Missense Mutation (SNP) | VAF 57/226 reads (25%) | SIFT tolerated (0.23); PolyPhen benign (0.094); called by muse, mutect2, varscan2
- ERICH6 | c.1787T>G p.L596R | Missense Mutation (SNP) | VAF 87/408 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FGF20 | c.126C>A p.S42R | Missense Mutation (SNP) | VAF 52/178 reads (29%) | SIFT tolerated (0.6); PolyPhen benign (0); called by muse, mutect2, varscan2
- FRMPD4 | c.278C>A p.A93E | Missense Mutation (SNP) | VAF 26/250 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- FZD9 | c.182T>A p.L61Q | Missense Mutation (SNP) | VAF 27/106 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); called by muse, mutect2, varscan2
- GABRE | c.585C>G p.C195W | Missense Mutation (SNP) | VAF 10/292 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- GLDC | c.1666-2A>T p.X556_splice | Splice Site (SNP) | VAF 91/812 reads (11%) | called by muse, mutect2, varscan2
- GMCL2 | c.705G>T p.W235C | Missense Mutation (SNP) | VAF 104/464 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GPR101 | c.1155C>G p.S385R | Missense Mutation (SNP) | VAF 57/180 reads (32%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.452); called by muse, mutect2, varscan2
- HAP1 | c.772G>T p.D258Y | Missense Mutation (SNP) | VAF 60/339 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HEPH | c.180C>A p.S60R (on ENST00000343002; = p.S114R on NM_138737.5) | Missense Mutation (SNP) | VAF 38/118 reads (32%) | SIFT tolerated (0.3); PolyPhen benign (0); called by muse, varscan2
- HFM1 | c.3975-1G>C p.X1325_splice | Splice Site (SNP) | VAF 82/288 reads (28%) | called by muse, varscan2
- IGLON5 | c.567G>T p.Q189H | Missense Mutation (SNP) | VAF 24/240 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- IL18RAP | c.1733_1734insA p.Q580Sfs*7 | Frame Shift Ins (INS) | VAF 45/258 reads (17%) | called by mutect2, pindel, varscan2
- INKA1 | c.159del p.L54Wfs*21 | Frame Shift Del (DEL) | VAF 17/130 reads (13%) | called by mutect2, pindel, varscan2
- INTS6L | c.137G>T p.R46L | Missense Mutation (SNP) | VAF 26/472 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.11); called by muse, mutect2
- IRX2 | c.509G>T p.R170L | Missense Mutation (SNP) | VAF 195/991 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IRX2 | c.223G>A p.A75T | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.003); called by muse, mutect2
- ISL1 | c.125G>T p.C42F | Missense Mutation (SNP) | VAF 128/631 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ISY1-RAB43 | c.490G>C p.D164H | Missense Mutation (SNP) | VAF 84/509 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ITGA2B | c.2686G>T p.E896* | Nonsense Mutation (SNP) | VAF 18/198 reads (9%) | called by muse, mutect2
- KALRN | c.608G>T p.R203L | Missense Mutation (SNP) | VAF 182/815 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- KCNB2 | c.1144G>A p.V382I | Missense Mutation (SNP) | VAF 67/409 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- KIF17 | c.2793+2T>A p.X931_splice | Splice Site (SNP) | VAF 207/779 reads (27%) | called by muse, mutect2, varscan2
- KLHL15 | c.958G>T p.D320Y | Missense Mutation (SNP) | VAF 20/278 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.157); called by muse, mutect2
- KNL1 | c.6955G>C p.E2319Q (on ENST00000346991 / NM_170589.5; = p.E2293Q on NM_144508.5) | Missense Mutation (SNP) | VAF 20/296 reads (7%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.59); called by muse, mutect2
- LAMA2 | c.6927C>A p.D2309E | Missense Mutation (SNP) | VAF 186/679 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LILRB1 | c.239C>A p.P80H (on ENST00000427581; = p.P44H on NM_006669.6) | Missense Mutation (SNP) | VAF 52/344 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- LRFN3 | c.1332G>C p.Q444H | Missense Mutation (SNP) | VAF 28/137 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- LRP1B | c.1045G>T p.A349S | Missense Mutation (SNP) | VAF 76/319 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- LTBP1 | c.3544G>T p.G1182W (on ENST00000404816 / NM_206943.4; = p.G856W on NM_000627.4) | Missense Mutation (SNP) | VAF 114/618 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MAGEH1 | c.374A>T p.Q125L | Missense Mutation (SNP) | VAF 38/597 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.023); called by muse, mutect2
- MEGF10 | c.449G>T p.S150I | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.806); called by muse, mutect2, varscan2
- MICAL3 | c.2662C>A p.P888T | Missense Mutation (SNP) | VAF 92/411 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- MIOS | c.1930G>T p.G644* | Nonsense Mutation (SNP) | VAF 58/278 reads (21%) | called by muse, mutect2, varscan2
- MOCOS | c.1432G>T p.V478F | Missense Mutation (SNP) | VAF 139/588 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); called by muse, mutect2, varscan2
- MPPE1 | c.178G>T p.D60Y | Missense Mutation (SNP) | VAF 59/470 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.169); called by muse, varscan2
- MXRA5 | c.8155C>A p.P2719T | Missense Mutation (SNP) | VAF 49/474 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.25); called by muse, mutect2, varscan2
- MYF6 | c.551G>C p.S184T | Missense Mutation (SNP) | VAF 89/700 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- MYO1E | c.1805+2T>C p.X602_splice | Splice Site (SNP) | VAF 23/656 reads (4%) | called by muse, mutect2
- NKTR | c.45del p.N16Tfs*57 | Frame Shift Del (DEL) | VAF 41/226 reads (18%) | called by mutect2, pindel, varscan2
- NKX2-6 | c.683C>A p.P228H | Missense Mutation (SNP) | VAF 69/245 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- NLRP3 | c.2825A>T p.Q942L | Missense Mutation (SNP) | VAF 261/908 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.101); called by muse, mutect2, varscan2
- NRG3 | c.1473C>A p.F491L | Missense Mutation (SNP) | VAF 76/246 reads (31%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.641); called by muse, mutect2, varscan2
- NRXN1 | c.2608C>A p.Q870K | Missense Mutation (SNP) | VAF 96/495 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- OLFML2B | c.1410G>T p.W470C | Missense Mutation (SNP) | VAF 82/284 reads (29%) | SIFT tolerated (0.05); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- ONECUT2 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 69/300 reads (23%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.403); called by muse, mutect2, varscan2
- OPRPN | c.200C>A p.P67Q | Missense Mutation (SNP) | VAF 131/518 reads (25%) | SIFT tolerated, low confidence (0.41); PolyPhen possibly damaging (0.722); called by muse, mutect2, varscan2
- OR11H1 | c.436G>T p.A146S | Missense Mutation (SNP) | VAF 71/367 reads (19%) | SIFT tolerated (0.51); PolyPhen benign (0.051); called by mutect2, varscan2
- OR14A2 | c.493C>A p.P165T | Missense Mutation (SNP) | VAF 117/401 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.121); called by muse, mutect2, varscan2
- OR1L1 | c.869C>T p.T290I (on ENST00000373686; = p.T240I on NM_001005236.3) | Missense Mutation (SNP) | VAF 41/326 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- OR4A16 | c.860T>A p.L287* | Nonsense Mutation (SNP) | VAF 55/268 reads (21%) | called by muse, mutect2, varscan2
- OR4K14 | c.511G>A p.G171S | Missense Mutation (SNP) | VAF 99/382 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- OR51E2 | c.793A>T p.N265Y | Missense Mutation (SNP) | VAF 178/844 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.36); called by muse, mutect2, varscan2
- OR5T2 | c.360G>T p.M120I | Missense Mutation (SNP) | VAF 35/173 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- OR8G1 | c.733A>T p.M245L | Missense Mutation (SNP) | VAF 119/513 reads (23%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- OR8J3 | c.173C>A p.P58H | Missense Mutation (SNP) | VAF 86/415 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- PALM | c.548G>T p.G183V | Missense Mutation (SNP) | VAF 56/188 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- PAPPA2 | c.920-1G>T p.X307_splice | Splice Site (SNP) | VAF 46/179 reads (26%) | called by muse, varscan2
- PCDHA4 | c.2160_2161del p.L721Afs*41 | Frame Shift Del (DEL) | VAF 91/517 reads (18%) | called by pindel, varscan2
- PCDHGA3 | c.2236G>T p.V746F | Missense Mutation (SNP) | VAF 173/836 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.916); called by muse, mutect2
- PFKL | c.532A>G p.T178A | Missense Mutation (SNP) | VAF 84/420 reads (20%) | SIFT tolerated (0.52); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PITPNM1 | c.2877G>T p.M959I | Missense Mutation (SNP) | VAF 22/89 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- PJA2 | c.37G>T p.D13Y | Missense Mutation (SNP) | VAF 99/477 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- PLCB2 | c.5C>G p.S2C | Missense Mutation (SNP) | VAF 8/102 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.97); called by muse, mutect2
- PLEKHG4B | c.2365G>T p.G789W (on ENST00000283426; = p.G1145W on NM_052909.5) | Missense Mutation (SNP) | VAF 56/204 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.787); called by muse, mutect2, varscan2
- PRPS2 | c.195C>A p.D65E | Missense Mutation (SNP) | VAF 30/249 reads (12%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.526); called by muse, mutect2, varscan2
- PTPRQ | c.5977A>T p.K1993* (on ENST00000616559; = p.K1951* on NM_001145026.2) | Nonsense Mutation (SNP) | VAF 134/480 reads (28%) | called by muse, mutect2, varscan2
- R3HDM1 | c.838A>T p.S280C | Missense Mutation (SNP) | VAF 30/160 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- RADX | c.2507T>A p.L836* | Nonsense Mutation (SNP) | VAF 12/163 reads (7%) | called by muse, mutect2
- RALGAPA1 | c.977G>T p.G326V | Missense Mutation (SNP) | VAF 253/566 reads (45%) | SIFT tolerated (0.11); PolyPhen benign (0.314); called by muse, mutect2, varscan2
- RFT1 | c.352C>T p.H118Y | Missense Mutation (SNP) | VAF 136/708 reads (19%) | SIFT tolerated (0.37); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- RGS12 | c.2572G>T p.G858C | Missense Mutation (SNP) | VAF 41/115 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.927); called by muse, mutect2, varscan2
- SAMSN1 | c.608G>A p.W203* | Nonsense Mutation (SNP) | VAF 69/438 reads (16%) | called by muse, mutect2, varscan2
- SEMA3A | c.547G>T p.D183Y | Missense Mutation (SNP) | VAF 66/258 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- SERPINB5 | c.318C>A p.S106R | Missense Mutation (SNP) | VAF 50/208 reads (24%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.858); called by muse, mutect2, varscan2
- SETMAR | c.22A>G p.T8A | Missense Mutation (SNP) | VAF 66/377 reads (18%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.061); called by muse, mutect2, varscan2
- SH3RF2 | c.951del p.R318Afs*4 | Frame Shift Del (DEL) | VAF 153/721 reads (21%) | called by mutect2, pindel, varscan2
- SLC5A5 | c.1718C>A p.S573* | Nonsense Mutation (SNP) | VAF 91/836 reads (11%) | called by muse, mutect2, varscan2
- SPACA1 | c.509T>C p.L170P | Missense Mutation (SNP) | VAF 77/221 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- SYCP2 | c.3926G>A p.R1309K | Missense Mutation (SNP) | VAF 56/320 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.164); called by muse, mutect2, varscan2
- SYT3 | c.1437del p.R480Gfs*3 | Frame Shift Del (DEL) | VAF 19/75 reads (25%) | called by mutect2, pindel, varscan2
- TAS2R3 | c.94G>T p.G32C | Missense Mutation (SNP) | VAF 68/331 reads (21%) | SIFT tolerated (0.19); PolyPhen benign (0.104); called by muse, mutect2, varscan2
- TBC1D31 | c.190G>A p.G64R | Missense Mutation (SNP) | VAF 44/349 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TCEAL3 | c.112G>T p.V38L | Missense Mutation (SNP) | VAF 27/470 reads (6%) | SIFT tolerated (0.34); PolyPhen benign (0.06); called by muse, mutect2
- TCHH | c.5539dup p.A1847Gfs*14 | Frame Shift Ins (INS) | VAF 89/483 reads (18%) | called by mutect2, pindel, varscan2
- TEX13C | c.1619G>T p.G540V | Missense Mutation (SNP) | VAF 239/868 reads (28%) | SIFT tolerated (0.1); called by muse, varscan2
- TMPRSS15 | c.2166-1G>T p.X722_splice | Splice Site (SNP) | VAF 119/502 reads (24%) | called by mutect2, varscan2
- UNC79 | c.4897G>T p.V1633L (on ENST00000393151 / NM_001346218.2; = p.V1456L on NM_020818.5) | Missense Mutation (SNP) | VAF 55/487 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- VCAN | c.3613A>T p.S1205C | Missense Mutation (SNP) | VAF 66/389 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); called by muse, mutect2, varscan2
- XKR3 | c.802T>G p.L268V | Missense Mutation (SNP) | VAF 91/396 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- ZBED9 | c.1335G>T p.Q445H | Missense Mutation (SNP) | VAF 81/274 reads (30%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.367); called by muse, mutect2, varscan2
- ZFP36L1 | c.97_98dup p.C34Vfs*47 | Frame Shift Ins (INS) | VAF 229/1055 reads (22%) | called by mutect2, pindel, varscan2
- ZNF584 | c.886A>T p.R296W | Missense Mutation (SNP) | VAF 114/386 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- ACTC1 | c.603C>A p.S201= | Silent (SNP) | VAF 22/326 reads (7%) | called by muse, mutect2
- ATP9B | c.2697C>G p.A899= | Silent (SNP) | VAF 38/108 reads (35%) | called by muse, mutect2, varscan2
- C20orf27 | c.54G>A p.A18= (on ENST00000379772 / NM_001258429.2; = p.A43= on NM_001039140.3) | Silent (SNP) | VAF 55/410 reads (13%) | catalogued as rs756037326; called by muse, mutect2, varscan2
- CA5A | c.279G>T p.L93= | Silent (SNP) | VAF 53/286 reads (19%) | called by muse, mutect2, varscan2
- CASS4 | c.1131G>C p.A377= | Silent (SNP) | VAF 104/619 reads (17%) | catalogued as COSV64387889; called by muse, mutect2, varscan2
- CHM | c.1707A>G p.P569= | Silent (SNP) | VAF 122/365 reads (33%) | catalogued as rs1335615431; called by muse, mutect2, varscan2
- CLEC14A | c.546G>A p.P182= | Silent (SNP) | VAF 33/471 reads (7%) | catalogued as rs767570743; called by muse, mutect2
- CNGB1 | c.2451C>A p.G817= | Silent (SNP) | VAF 154/872 reads (18%) | catalogued as rs1174140196; called by muse, mutect2, varscan2
- COLQ | c.729G>T p.G243= | Silent (SNP) | VAF 52/344 reads (15%) | catalogued as rs941592757; called by muse, mutect2, varscan2
- CPA5 | c.171G>T p.G57= | Silent (SNP) | VAF 119/537 reads (22%) | called by muse, mutect2, varscan2
- CTNND2 | c.1347C>T p.H449= | Silent (SNP) | VAF 97/349 reads (28%) | called by muse, mutect2, varscan2
- DACH2 | c.195C>T p.T65= | Silent (SNP) | VAF 29/325 reads (9%) | called by muse, mutect2
- DOK3 | c.1083G>A p.P361= | Silent (SNP) | VAF 50/287 reads (17%) | catalogued as rs147796245; called by muse, mutect2, varscan2
- DPP10 | c.1587G>A p.K529= | Silent (SNP) | VAF 36/244 reads (15%) | catalogued as rs1249104064, COSV59681690; called by muse, mutect2, varscan2
- DRC7 | c.1677C>T p.L559= | Silent (SNP) | VAF 94/479 reads (20%) | called by muse, mutect2, varscan2
- EPG5 | c.7218G>T p.V2406= | Silent (SNP) | VAF 86/326 reads (26%) | called by muse, mutect2, varscan2
- EPHA3 | c.2160C>A p.V720= | Silent (SNP) | VAF 70/300 reads (23%) | called by muse, mutect2, varscan2
- FAM47B | c.450G>T p.L150= | Silent (SNP) | VAF 35/198 reads (18%) | called by muse, mutect2, varscan2
- GIMAP1 | c.39C>G p.V13= | Silent (SNP) | VAF 56/313 reads (18%) | called by muse, mutect2, varscan2
- GPR149 | c.877C>A p.R293= | Silent (SNP) | VAF 144/619 reads (23%) | called by muse, mutect2, varscan2
- GPR55 | c.306C>T p.F102= | Silent (SNP) | VAF 75/368 reads (20%) | catalogued as rs144507378; called by muse, mutect2, varscan2
- GRID1 | c.669G>C p.T223= | Silent (SNP) | VAF 195/704 reads (28%) | called by muse, mutect2, varscan2
- HORMAD2 | c.273T>C p.F91= | Silent (SNP) | VAF 48/213 reads (23%) | called by muse, mutect2, varscan2
- HTR1D | c.360G>T p.T120= | Silent (SNP) | VAF 100/363 reads (28%) | catalogued as COSV58448212; called by muse, mutect2, varscan2
- IGKV1-16 | c.33G>C p.G11= | Silent (SNP) | VAF 116/627 reads (19%) | catalogued as rs552338386; called by muse, mutect2, varscan2
- KCNJ5 | c.1180C>T p.L394= | Silent (SNP) | VAF 26/144 reads (18%) | catalogued as COSV100610792; called by muse, mutect2, varscan2
- KIF21B | c.4302C>A p.A1434= (on ENST00000422435 / NM_001252100.2; = p.A1421= on NM_017596.4) | Silent (SNP) | VAF 79/240 reads (33%) | catalogued as COSV100144039; called by muse, mutect2, varscan2
- KIF4B | c.114G>A p.E38= | Silent (SNP) | VAF 179/749 reads (24%) | catalogued as COSV70531618; called by muse, mutect2, varscan2
- LAMP5 | c.774C>A p.V258= | Silent (SNP) | VAF 65/388 reads (17%) | catalogued as COSV55717107; called by muse, mutect2, varscan2
- MS4A14 | c.663A>C p.P221= | Silent (SNP) | VAF 93/333 reads (28%) | called by muse, mutect2, varscan2
- MYO7A | c.672G>T p.R224= | Silent (SNP) | VAF 71/351 reads (20%) | called by muse, mutect2, varscan2
- NLRC4 | c.333C>A p.T111= | Silent (SNP) | VAF 31/159 reads (19%) | called by muse, mutect2, varscan2
- OR10T2 | c.480C>A p.A160= | Silent (SNP) | VAF 105/458 reads (23%) | catalogued as COSV57781497; called by muse, mutect2, varscan2
- OR13C2 | c.852T>C p.Y284= | Silent (SNP) | VAF 32/250 reads (13%) | catalogued as rs1479693984; called by muse, mutect2, varscan2
- OR1J4 | c.735C>G p.L245= | Silent (SNP) | VAF 59/215 reads (27%) | catalogued as COSV100534315; called by muse, mutect2, varscan2
- OR2AK2 | c.729C>T p.S243= | Silent (SNP) | VAF 96/490 reads (20%) | catalogued as COSV63549460; called by muse, mutect2, varscan2
- OR6C74 | c.258T>A p.G86= | Silent (SNP) | VAF 33/123 reads (27%) | called by muse, mutect2, varscan2
- PCDH8 | c.2700C>A p.S900= | Silent (SNP) | VAF 292/870 reads (34%) | called by muse, mutect2, varscan2
- PITX2 | c.912C>T p.S304= (on ENST00000354925 / NM_001204397.1; = p.S311= on NM_000325.6) | Silent (SNP) | VAF 135/437 reads (31%) | catalogued as COSV100146460; called by muse, mutect2, varscan2
- PRDM2 | c.684G>A p.Q228= | Silent (SNP) | VAF 90/384 reads (23%) | catalogued as COSV52446099; called by muse, mutect2, varscan2
- PRPF3 | c.375G>C p.V125= | Silent (SNP) | VAF 41/694 reads (6%) | catalogued as COSV104411803; called by muse, mutect2
- PTPRB | c.1227G>T p.R409= | Silent (SNP) | VAF 42/192 reads (22%) | catalogued as COSV54255546; called by muse, mutect2, varscan2
- PXDNL | c.2244C>G p.A748= | Silent (SNP) | VAF 43/172 reads (25%) | called by muse, mutect2, varscan2
- QDPR | c.378C>T p.L126= | Silent (SNP) | VAF 160/522 reads (31%) | called by muse, mutect2, varscan2
- RAPGEF4 | c.1074C>A p.S358= | Silent (SNP) | VAF 53/310 reads (17%) | catalogued as COSV99911429; called by muse, mutect2, varscan2
- RTP5 | c.108G>A p.P36= | Silent (SNP) | VAF 26/120 reads (22%) | catalogued as rs777977897; called by muse, mutect2, varscan2
- SASH3 | c.529C>A p.R177= | Silent (SNP) | VAF 36/374 reads (10%) | called by muse, mutect2
- SERPINB2 | c.984C>T p.G328= | Silent (SNP) | VAF 75/443 reads (17%) | called by muse, mutect2, varscan2
- SHISA5 | c.720C>G p.L240= | Silent (SNP) | VAF 131/550 reads (24%) | called by muse, mutect2, varscan2
- SLC35G1 | c.747G>C p.V249= (on ENST00000427197 / NM_001134658.3; = p.V248= on NM_153226.4) | Silent (SNP) | VAF 133/371 reads (36%) | called by muse, mutect2, varscan2
- SLITRK2 | c.1971C>A p.T657= | Silent (SNP) | VAF 35/350 reads (10%) | catalogued as COSV59423838; called by muse, mutect2
- SRPX2 | c.1122G>T p.R374= | Silent (SNP) | VAF 56/852 reads (7%) | called by muse, mutect2
- TNNT2 | c.547C>A p.R183= | Silent (SNP) | VAF 215/1092 reads (20%) | catalogued as rs727503512, CM127304; called by muse, mutect2, varscan2
- WDR44 | c.717A>T p.P239= | Silent (SNP) | VAF 32/478 reads (7%) | called by muse, mutect2
- WDR77 | c.786G>T p.V262= | Silent (SNP) | VAF 48/167 reads (29%) | called by muse, mutect2, varscan2
- ZMAT2 | c.351C>T p.S117= | Silent (SNP) | VAF 69/274 reads (25%) | called by muse, mutect2, varscan2
- ZNF280A | c.258G>A p.V86= | Silent (SNP) | VAF 20/380 reads (5%) | called by muse, mutect2
- AC009093.9 | n.1174C>A | RNA (SNP) | VAF 74/336 reads (22%) | called by mutect2, varscan2
- AC116903.1 | n.417+187G>A | Intron (SNP) | VAF 34/427 reads (8%) | called by muse, mutect2
- ADAM21P1 | n.1843C>A | RNA (SNP) | VAF 63/444 reads (14%) | called by muse, mutect2, varscan2
- AMPH | c.1183-905G>T | Intron (SNP) | VAF 71/295 reads (24%) | called by muse, mutect2, varscan2
- BLOC1S5-TXNDC5 | c.372+38765G>T | Intron (SNP) | VAF 146/676 reads (22%) | called by muse, mutect2, varscan2
- CDC45 | c.542+149C>T | Intron (SNP) | VAF 204/1056 reads (19%) | catalogued as rs1340232545, COSV99596324; called by muse, mutect2, varscan2
- FABP5P3 | chr7:152446196 G>T | 3'Flank (SNP) | VAF 186/760 reads (24%) | called by muse, mutect2, varscan2
- GABRA6 | c.530-71T>A | Intron (SNP) | VAF 8/135 reads (6%) | called by muse, mutect2
- GM2A | c.*29G>T | 3'UTR (SNP) | VAF 134/709 reads (19%) | called by muse, mutect2, varscan2
- GRXCR1 | c.-38C>A | 5'UTR (SNP) | VAF 78/245 reads (32%) | called by muse, mutect2, varscan2
- GVINP1 | n.3237C>G | RNA (SNP) | VAF 81/306 reads (26%) | catalogued as rs1388168336; called by muse, mutect2, varscan2
- HYDIN | c.382-95G>A | Intron (SNP) | VAF 56/304 reads (18%) | called by muse, mutect2, varscan2
- IFRD2 | c.-73T>C | 5'UTR (SNP) | VAF 48/369 reads (13%) | called by muse, mutect2, varscan2
- INS | c.*36C>T | 3'UTR (SNP) | VAF 128/602 reads (21%) | catalogued as rs755609237; called by muse, mutect2, varscan2
- LIM2 | c.*43G>T | 3'UTR (SNP) | VAF 98/304 reads (32%) | called by muse, mutect2, varscan2
- MAU2 | c.*297C>T | 3'UTR (SNP) | VAF 12/169 reads (7%) | called by muse, mutect2
- MDS2 | n.943_944del | RNA (DEL) | VAF 38/204 reads (19%) | called by pindel, varscan2
- MGLL | c.481-4980A>T | Intron (SNP) | VAF 56/266 reads (21%) | called by muse, varscan2
- MIR1468 | chrX:63785155 G>C | 3'Flank (SNP) | VAF 15/195 reads (8%) | catalogued as COSV100884549; called by muse, mutect2
- MPV17 | c.71-2986G>T | Intron (SNP) | VAF 102/362 reads (28%) | called by muse, mutect2, varscan2
- OR2M1P | n.495del | RNA (DEL) | VAF 159/611 reads (26%) | called by mutect2, varscan2
- OR2W5 | n.1174C>T | RNA (SNP) | VAF 120/668 reads (18%) | catalogued as rs1558225809; called by muse, varscan2
- PAX7 | c.1402+96G>T | Intron (SNP) | VAF 47/190 reads (25%) | called by muse, mutect2, varscan2
- PAX7 | c.1402+97G>T | Intron (SNP) | VAF 45/186 reads (24%) | called by muse, mutect2, varscan2
- PDE3A | c.1011+56G>C | Intron (SNP) | VAF 120/637 reads (19%) | catalogued as rs970840203; called by muse, mutect2, varscan2
- PDE4A | chr19:10417758 G>T | 5'Flank (SNP) | VAF 98/330 reads (30%) | called by muse, mutect2, varscan2
- PKD1L2 | n.3196C>T | RNA (SNP) | VAF 76/334 reads (23%) | called by muse, mutect2, varscan2
- PRDM11 | c.657-6757G>T | Intron (SNP) | VAF 38/156 reads (24%) | called by muse, mutect2
- RNA5-8SP2 | chr16:34158961 C>T | 5'Flank (SNP) | VAF 59/285 reads (21%) | called by muse, mutect2, varscan2
- SYCE1 | chr10:133567850 G>T | 5'Flank (SNP) | VAF 7/28 reads (25%) | called by muse, mutect2
- TBC1D3F | c.*38C>A | 3'UTR (SNP) | VAF 267/699 reads (38%) | called by muse, mutect2, varscan2
- TERB2 | c.65-32G>C | Intron (SNP) | VAF 103/404 reads (25%) | called by muse, mutect2, varscan2
- THNSL2 | c.1229+102G>T | Intron (SNP) | VAF 110/448 reads (25%) | called by muse, mutect2, varscan2
- TPO | c.482+2466G>A | Intron (SNP) | VAF 53/360 reads (15%) | called by muse, mutect2, varscan2
- ZNF605 | c.-6C>T | 5'UTR (SNP) | VAF 82/726 reads (11%) | catalogued as rs897990392; called by muse, varscan2
